Surgical pathology report (de-identified scan), TCGA case TCGA-RQ-AAAT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RQ-AAAT-01A (Primary Tumor).

ICD O-3
Lymphoma, diffuse large B-cell 9680/3
Site: Cerebellopontine angle C71.6
Jt 5/16/14

Addendum Diagnosis:

Cerebellopontine angle mass, biopsy and resection:

Diffuse Large Cell B-Cell Lymphoma, follicular center cell type

Microscopic Description:

Microscopic evaluation reveals a malignant neoplasm composed of sheets of atypical cells. The tumor cells demonstrate pleomorphic hyperchromatic nuclei and significant cytologic atypia. Foci of tumor necrosis as well as individual apoptotic neoplastic cells are seen. Numerous mitotic figures are seen. The tumor cells demonstrate diffuse brown CD45 and CD20 positivity. They are negative for fresh and of keratin AE1 AE3. CD3 highlights scattered background T cells. The histologic features are consistent with a B-cell lymphoma. A final diagnosis will be issued pending review of additional stains, as well as hematopathology consultation.

Addendum Microscopic Description:

The immunophenotype of the tumor is as follows:

CD45 positive

CD20 positive

CD10 positive

MUM-1 positive

BCL6 positive

CD3 negative

CD43 negative

CD30 negative

BCL2 Negative

Source: NCI Genomic Data Commons file fefbdee2-4353-4340-b53d-48537c3404cd (TCGA-RQ-AAAT.66B90AE3-785B-4866-8B56-7B3B37EF38B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).